RC case RC-B5D5 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/43c4ea47-7b40-46c6-9c91-7766b5e0bee2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1997; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Peripheral T-cell lymphoma, NOS: ICD-O-3 morphology code: 9702/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 19.5 years (7,130 days); Year of diagnosis: 2016; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low Risk; Sites of involvement: Peripheral blood.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 683 days (1.9 years); Days to treatment end: 744 days (2.0 years); Treatment outcome: Stable Disease; Reason treatment ended: Adverse Event; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Other; Initial disease status: Initial Diagnosis; Days to treatment start: 1,163 days (3.2 years); Days to treatment end: 1,169 days (3.2 years); Reason treatment ended: Other; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Stable Disease; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 100.
- Day 1,548 (end of treatment course 1): Disease response: With Tumor.
- Days to follow up: 1,898 days (5.2 years); Disease response: With Tumor.

Molecular and laboratory tests
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 254 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus: Negative [Test analyte type: DNA].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 69.9 kg; Height: 184 cm; BMI: 20.6.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B5D5-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B5D5-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
  Slide RC-B5D5-TBP1-A-1-0-CS2: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 100; Percent stromal cells: 0; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
